Somatic mutation profile of tumor specimen TCGA-J4-A83L-01A (aliquot TCGA-J4-A83L-01A-11D-A34U-08) from TCGA case TCGA-J4-A83L, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.2 years (22,338 days).
Specimen TCGA-J4-A83L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae673ed2-bbac-43d1-97f1-3dd740216853.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A83L-10A (Blood Derived Normal), aliquot TCGA-J4-A83L-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/800bbce6-6aa2-46c9-9298-82113c8c0264

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO1 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100008438; called by muse, mutect2, varscan2
- ALS2CL | c.1257T>G p.C419W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV100015232; called by muse, mutect2, varscan2
- B3GALT4 | c.320C>G p.T107R | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV101005676, COSV65851214; called by muse, mutect2, varscan2
- CCDC8 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100282126; called by muse, mutect2, varscan2
- IRAG1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV101351489; called by muse, mutect2, varscan2
- MTUS2 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV70916396; called by muse, mutect2, varscan2
- SECISBP2L | c.2419T>G p.L807V (on ENST00000559471 / NM_001193489.2; = p.L762V on NM_014701.4) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99960761; called by muse, mutect2
- SF3B1 | c.1866G>C p.E622D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as rs763149798, COSV59205621, COSV59206479; called by muse, mutect2
- WDR48 | c.20A>G p.Q7R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs751315524, COSV100176811; called by muse, mutect2, varscan2
- CANT1 | c.477G>A p.A159= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as rs149367726; called by muse, mutect2
- CDH10 | c.1170G>C p.L390= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100052524, COSV52571036; called by muse, mutect2, varscan2
- CNTNAP5 | c.1251G>T p.L417= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV101443484, COSV101443881; called by muse, mutect2, varscan2
- MCM10 | c.144C>T p.A48= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs773799997, COSV101098335; called by muse, mutect2, varscan2
- NCOR1 | c.3063C>T p.G1021= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs546064182, COSV99251310; called by muse, mutect2, varscan2
- TBPL2 | c.357C>T p.H119= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs369692725, COSV55972786; called by muse, mutect2, varscan2
- SNORD115-29 | n.51A>G | RNA (SNP) | VAF 23/503 reads (5%) | called by muse, mutect2
